Gene-level copy-number profile of tumor specimen HCM-SANG-0281-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0281-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0281-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 79467479-24dc-4137-ab50-a9465e354953.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0281-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/e1c94526-4b6a-43a8-81a4-c897c7c0fe4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 767; copy number 2: 22,388; copy number 3: 14,367; copy number 4: 15,322; copy number 5: 3,654; copy number 6: 1,022; copy number 8: 66; copy number 9: 731; copy number 10: 57; copy number 11: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,556 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:149,446,795–161,274,061, 232 genes, copy number 5 (broad region; genes not listed).
- chr6:167,357,033–170,738,536, 68 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:37,032–34,299,012, 585 genes, copy number 5–6 (broad region; genes not listed).
- chr7:64,794,388–66,495,758, 60 genes, copy number 5: ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, ZNF273, AC073349.1, VN1R42P, MTDHP1, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1, AC114501.2, AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4.
- chr8:39,451,045–39,522,852, 1 gene, copy number 8: ADAM3A.
- chr8:42,849,637–83,294,271, 581 genes, copy number 5 (broad region; genes not listed).
- chr8:83,912,713–120,056,201, 502 genes, copy number 5 (broad region; genes not listed).
- chr8:120,380,761–120,542,133, 2 genes, copy number 5 (within-gene range 4–5): MRPL13, MTBP.
- chr11:2,444,684–8,594,289, 299 genes, copy number 5 (broad region; genes not listed).
- chr11:8,980,576–18,322,198, 181 genes, copy number 5 (broad region; genes not listed).
- chr12:44,508,275–52,309,163, 270 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:52,298,856–52,306,287, 1 gene, copy number 5: AC121757.2.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 5–6 (broad region; genes not listed).
- chr17:22,519,617–22,706,703, 14 genes, copy number 8: MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr17:46,243,606–46,579,691, 12 genes, copy number 5: MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr20:87,250–16,053,197, 286 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 6 (within-gene range 1–6): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,105 genes, copy number 6–11 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
